CPTAC case C3L-02219 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e044f20-ff60-47ab-b547-fbee99155c4a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 931 days (2.5 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 77.6 years (28,347 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 931 days (2.5 years); Progression or recurrence: yes; Days to recurrence: 217 days; Days to last follow up: 931 days (2.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 8.4 cm); Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 9; Margin status: Involved.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 351 days; Disease response: With Tumor.
- Days to follow up: 694 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 931 days (2.5 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 217 days.

Other clinical attributes
- Weight: 94 kg; Height: 170 cm; BMI: 32.53; DLCO (% of predicted): 88; FEV1/FVC before bronchodilator (%): 79.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 20; Cigarettes per day: 20; Tobacco smoking onset year: 1984; Tobacco smoking quit year: 2004; Exposure duration years: 20.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02219-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 300 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02219-21: Section location: Right Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02219-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 243 mg.
- Sample C3L-02219-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 387 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02219-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
